Somatic mutation profile of tumor specimen TCGA-BR-6455-01A (aliquot TCGA-BR-6455-01A-11D-1800-08) from TCGA case TCGA-BR-6455, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-BR-6455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b5e2804-e2ee-4c34-86bd-ad763630b987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6455-10A (Blood Derived Normal), aliquot TCGA-BR-6455-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb6cd25-ddbb-415e-b121-9fd63f0e6731

The open-access MAF lists 100 somatic variants for this specimen: 69 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 60, Silent 31, Nonsense Mutation 4, Splice Region 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 58/162 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV61827486; called by muse, mutect2, varscan2
- ADORA1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs766823930, COSV55141245; called by muse, mutect2, varscan2
- ALG10 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56791650; called by muse, mutect2
- ARFGEF2 | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64210405; called by muse, mutect2, varscan2
- ARID1A | c.6773T>G p.L2258R | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61371660; called by muse, mutect2, varscan2
- BAHCC1 | c.6767C>T p.A2256V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1555659277, COSV57022736; called by muse, mutect2, varscan2
- BCOR | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60699532; called by muse, mutect2, varscan2
- BIRC3 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54814977; called by muse, mutect2, varscan2
- BPI | c.94G>A p.V32I (on ENST00000262865; = p.V28I on NM_001725.3) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs776005510, COSV53403846; called by muse, mutect2, varscan2
- BRD8 | c.3616G>A p.V1206I | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as rs1319496288, COSV54521843; called by muse, mutect2, varscan2
- C4orf33 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV55415329; called by muse, mutect2, varscan2
- CACNA1C | c.3664G>T p.E1222* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1555886938, COSV59696532, COSV59703144; called by muse, mutect2, varscan2
- CCDC122 | c.436T>C p.W146R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); catalogued as rs773933564, COSV55708680; called by muse, mutect2, varscan2
- CDPF1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs151250954; called by muse, mutect2, varscan2
- CLDN14 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs922801470, COSV59771607; called by muse, mutect2, varscan2
- CNTF | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 38/152 reads (25%) | catalogued as rs1294896892, COSV60157133; called by muse, mutect2, varscan2
- COL12A1 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767743127, COSV59389382; called by muse, mutect2, varscan2
- CTNNA2 | c.33A>T p.K11N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV63546483; called by muse, mutect2, varscan2
- DGKE | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752681978, COSV52348821; called by muse, mutect2, varscan2
- DNAH1 | c.8035G>A p.V2679I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756765619, COSV70226371; called by muse, mutect2, varscan2
- DNAH1 | c.10328G>A p.R3443H | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752391361, COSV70226372; called by muse, mutect2, varscan2
- EBF1 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167179; called by muse, mutect2, varscan2
- EFCAB12 | c.148T>A p.F50I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100394510; called by muse, mutect2, varscan2
- EPHX4 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV64888983; called by muse, mutect2, varscan2
- FAM135B | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs554108334, COSV52704532; called by muse, mutect2, varscan2
- FAM180A | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV58527801; called by muse, mutect2, varscan2
- FYB1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757886197, COSV60940974; called by muse, mutect2, varscan2
- GOLGA4 | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs751765583, COSV62709175; called by muse, mutect2, varscan2
- GRM1 | c.2369C>T p.T790I | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51108653; called by muse, mutect2, varscan2
- HYDIN | c.10619C>T p.A3540V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs578209969, COSV66857372; called by muse, mutect2, varscan2
- IFRD1 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50043662; called by muse, mutect2, varscan2
- ITPRIPL2 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs375194218, COSV67347310; called by muse, mutect2
- KCTD8 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1188294515, COSV63585337; called by muse, mutect2, varscan2
- MED29 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV55392454; called by muse, mutect2, varscan2
- MEIOB | c.881-1G>A p.X294_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | catalogued as rs1328762786, COSV58052882; called by muse, mutect2, varscan2
- MTHFD1 | c.1128-1G>C p.X376_splice | Splice Site (SNP) | VAF 27/72 reads (38%) | catalogued as COSV53697710; called by muse, varscan2
- MUC17 | c.3967G>A p.E1323K | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV60279777; called by muse, mutect2, varscan2
- MUC17 | c.9587C>A p.T3196N | Missense Mutation (SNP) | VAF 159/445 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV60279785; called by muse, mutect2, varscan2
- MYO3B | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs376278701; called by muse, mutect2, varscan2
- NCK1 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56636107; called by muse, mutect2, varscan2
- NDUFS3 | c.627G>A p.E209= | Splice Region (SNP) | VAF 130/550 reads (24%) | catalogued as COSV55453704; called by muse, mutect2, varscan2
- OBSCN | c.16639G>A p.V5547I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52739201; called by muse, mutect2, varscan2
- P4HA2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as rs201860203, COSV51323743; called by muse, mutect2, varscan2
- PCYOX1L | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51002083; called by muse, mutect2, varscan2
- PDGFA | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63279138; called by muse, mutect2, varscan2
- PLEC | c.7052C>T p.A2351V (on ENST00000322810 / NM_201380.4; = p.A2241V on NM_000445.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.113); catalogued as rs781956194, COSV59603050, COSV59642717; called by muse, mutect2, varscan2
- POLR2F | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs550998177, COSV50777649; called by muse, mutect2, varscan2
- POU5F2 | c.103T>G p.L35V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1185558398, COSV67933865; called by muse, mutect2, varscan2
- PSD4 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55524457; called by muse, mutect2, varscan2
- PYROXD2 | c.783T>C p.S261= | Splice Region (SNP) | VAF 86/127 reads (68%) | catalogued as COSV65328778; called by muse, mutect2, varscan2
- RBMS2 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV56262839; called by muse, mutect2, varscan2
- SAPCD2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1050174503, COSV68836359; called by muse, mutect2, varscan2
- SH3RF2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV63037029; called by muse, mutect2, varscan2
- SLC38A3 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68843883; called by muse, mutect2, varscan2
- SLC4A1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs186542577; called by muse, mutect2, varscan2
- TCHH | c.4729C>T p.R1577C | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV64272738; called by muse, mutect2, varscan2
- TEAD4 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373793296, COSV63280346; called by muse, mutect2, varscan2
- TEX44 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183366634; called by muse, mutect2, varscan2
- TTN | c.57114T>A p.D19038E (on ENST00000591111; = p.D11614E on NM_003319.4) | Missense Mutation (SNP) | VAF 77/283 reads (27%) | PolyPhen benign (0.003); catalogued as rs878956804, COSV59884039; called by muse, mutect2, varscan2
- VWA1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs376449591; called by muse, mutect2, varscan2
- WDSUB1 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63066933; called by muse, mutect2, varscan2
- YRDC | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV65988314; called by muse, mutect2, varscan2
- YTHDC2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV50736566; called by muse, mutect2, varscan2
- ZMYND15 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as rs200277327, COSV52639685; called by muse, mutect2, varscan2
- ZNF610 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58343520; called by muse, mutect2, varscan2
- ARID2 | c.5371_5372del p.K1791Efs*3 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.779G>C p.S260T | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY1 | c.429C>T p.G143= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV52029968; called by muse, mutect2, varscan2
- ALX1 | c.255A>G p.G85= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV57491119; called by muse, mutect2, varscan2
- AXIN1 | c.2319C>T p.G773= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs368430061; called by muse, mutect2, varscan2
- COL6A5 | c.6513G>A p.P2171= (on ENST00000312481; = p.P2167= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs750306317, COSV55202663; called by muse, mutect2, varscan2
- CYP19A1 | c.1449G>A p.E483= | Silent (SNP) | VAF 79/132 reads (60%) | catalogued as COSV53057041; called by muse, mutect2, varscan2
- DNAH1 | c.1704C>T p.A568= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1206321186, COSV70226367; called by muse, mutect2, varscan2
- EPB41L3 | c.2415G>A p.A805= | Silent (SNP) | VAF 117/341 reads (34%) | catalogued as rs1200791161, COSV100550817, COSV59444169; called by muse, mutect2, varscan2
- FBXW5 | c.1410C>T p.D470= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs765978255, COSV56402290; called by muse, mutect2, varscan2
- GREB1 | c.2817G>A p.P939= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs766981444, COSV52180385; called by muse, mutect2, varscan2
- LIN7B | c.297G>A p.T99= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs778771020, COSV55521040; called by muse, mutect2, varscan2
- LSM4 | c.264C>T p.R88= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs765934857, COSV53253296; called by muse, mutect2, varscan2
- MAFB | c.429C>T p.H143= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs571395644, COSV100965027; called by muse, mutect2
- MS4A8 | c.522C>T p.Y174= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as rs767555360, COSV55753043; called by muse, mutect2, varscan2
- MYH4 | c.1495C>T p.L499= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as COSV55112085; called by muse, mutect2, varscan2
- NID2 | c.1662G>A p.L554= | Silent (SNP) | VAF 60/202 reads (30%) | catalogued as rs763461550, COSV53492886; called by muse, mutect2, varscan2
- NR3C2 | c.2631A>G p.L877= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV60985288; called by muse, mutect2, varscan2
- NUP188 | c.4845T>C p.N1615= | Silent (SNP) | VAF 90/263 reads (34%) | catalogued as COSV65330104; called by muse, mutect2, varscan2
- OVCA2 | c.234G>A p.Q78= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV53983662; called by muse, mutect2, varscan2
- PDE6C | c.219G>A p.G73= | Silent (SNP) | VAF 49/60 reads (82%) | catalogued as COSV65114665; called by muse, mutect2, varscan2
- PKHD1 | c.11331G>T p.L3777= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs1445856949, COSV64381399; called by muse, mutect2, varscan2
- POGZ | c.1374C>T p.G458= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs1418593404, COSV55032114; called by muse, mutect2, varscan2
- PPP1R12C | c.1515G>A p.P505= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs746830894, COSV54735942; called by muse, mutect2, varscan2
- PPP3R2 | c.285G>A p.A95= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs971779491, COSV100701928, COSV62450522; called by muse, mutect2, varscan2
- PTGER3 | c.942C>T p.H314= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV60687533; called by muse, mutect2, varscan2
- PXDN | c.2271C>T p.G757= | Silent (SNP) | VAF 59/181 reads (33%) | catalogued as rs374573243, COSV53228546; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.6849G>A p.K2283= | Silent (SNP) | VAF 85/245 reads (35%) | catalogued as COSV63661185; called by muse, mutect2, varscan2
- SLC35D3 | c.639C>T p.H213= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59377409; called by muse, mutect2, varscan2
- SYNE1 | c.14115C>T p.A4705= (on ENST00000367255 / NM_182961.4; = p.A4634= on NM_033071.3) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs377739292; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBGCP6 | c.645C>T p.F215= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV50536485; called by muse, mutect2, varscan2
- TUFM | c.1125C>T p.S375= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV57948300; called by muse, mutect2, varscan2
- URGCP | c.1191C>T p.N397= (on ENST00000453200 / NM_001077663.3; = p.N388= on NM_017920.4) | Silent (SNP) | VAF 57/166 reads (34%) | catalogued as COSV56245027; called by muse, mutect2, varscan2
